Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A48K, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A48K-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Clinical Diagnosis & History:

year old with biopsy proven high grade leiomyosarcoma of right leg.
presents today for radical resection.

Specimens Submitted:

- 1: Right calf mass
- 2: Anterior margin of right calf

ICD-O3

leiomyosarcoma, NOS

88903

Site: calf, NOS

C49.2

91112 PD

DIAGNOSIS:

1. Right calf, mass; excision:

- High grade spindle cell sarcoma morphologically compatible with high grade leiomyosarcoma.
- Tumor shows focal osseous metaplasia.
- Tumor infiltrates skeletal muscle and deep subcutaneous tissue.
- Tumor size: 4.1 x 3.1 x 2.0 cm.
- Mitotic rate: 20 per 10 hpfs
- No necrosis present. Nuclear pleomorphism is seen.
- Surgical resection margins are negative. Focally the tumor is within 1mm of posterior margin limited by fibrous and adipose tissue.

2. Right calf, anterior margin; excision:

- Benign skeletal muscle and fibro connective tissue.
- No evidence of malignancy.

Note: Immunohistochemical stains show that the tumor cells are positive for h-Caldesmon, focally HHF35 and negative for SMA, desmin, S-100, HMB-45 and cytokeratin AE1/AE3. Even though SMA and desmin are negative, the morphological features and caldesmon positivity supports the above diagnosis.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under CLIA as qualified to perform high complexity clinical laboratory testing.

** Continued on next page **

[page 2 of 3]
SURGICAL [REDACTED]

----- Page 2 of 3

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is initially received fresh and labeled "Right calf mass." It consists of one, irregularly shaped, soft, tan-brown piece of muscular tissue (7.3 x 4.3 x 3.5 cm), to which is attached tan-white ellipse of skin (4.1 x 1.2 x 0.3 cm). The skin surface and outer surface of the muscular piece of tissue are both smooth and glistening. The specimen is received with two surgical sutures, which are oriented as follows: "long stitch anterior, short stitch superior." The specimen is then anatomically oriented and differentially inked as follows: anterior = yellow; posterior = green; superior = blue; inferior = black; medial = red; lateral = orange. The specimen is subsequently bisected transversely to reveal an ovoid, firm, tan-white mass (4.1 x 3.1 x 2.0 cm), which has a whorling cut surface. A portion of the mass and adjacent muscular tissue is submitted to Tissue Procurement Services. The remainder of the specimen is serially sectioned to reveal that the tumor is located within 0.1 cm of the inferior, medial, and posterior margin; all other margins are grossly free of tumor. No hemorrhage or necrosis is grossly identified on the cut surfaces. Representative sections are submitted. All margins are perpendicularly sectioned and submitted.

Summary of Sections:

TIP - Skin tips
SK - Skin, in relation to underlying tumor mass
SM - Superior Margin
IM - Inferior Margin
MM - Medial Margin
LM - Lateral Margin
AM - Anterior Margin
PM - Posterior Margin
T1 - Tumor mass, one full thickness section
T2 - Tumor mass, second full thickness section

2). The specimen is received in formalin, labeled "anterior margin of right calf" and consists of a piece of fibromuscular tissue measuring 4 x 2.5 cm, and 1.5 cm thick. A stitch marks the new margin of excision, which is inked black. No tumor is grossly identified. The tissue is serially sectioned and entirely submitted.

Summary of sections:

SS - sequential sections

** Continued on next page **

[page 3 of 3]
SURGICAL

Page 3 of 3

Summary of Sections:

Part 1: Right calf mass

Block	Sect.	Site	PCs
1		AM	1
1		IM	1
1		LM	1
1		MM	1
1		PM	1
1		SK	1
1		SM	1
3		T1	3
3		T2	3
1		TIP	1

Part 2: Anterior margin of right calf

Block	Sect.	Site	PCs
10		SS	10

** End of Report **

42813/12

Source: NCI Genomic Data Commons file 50bf0393-a38d-42f5-9e19-efa163d48ba8 (TCGA-DX-A48K.170A92E4-03A8-49EE-86F1-298EB79DE042.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).